Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4819, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4819-01A (Primary Tumor).

FINAL DIAGNOSIS

TCGA-B0-4819

PART 1: RIGHT PULMONARY TUMOR THROMBUS, EXCISION -
THROMBUS OF METASTATIC RENAL CELL CARCINOMA WITH EXTENSIVE NECROSIS.

PART 2: KIDNEY (903 GM.), RIGHT, RADICAL NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, CONVENTIONAL CLEAR CELL TYPE, WITH FOCAL ONCOCYTIC FEATURES (9.0 CM.)
- B. FUHRMAN NUCLEAR GRADE 3-4/4 (see comment).
- C. THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE.
- D. ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- E. VASCULAR RESECTION MARGIN IS INVOLVED BY THE CARCINOMA.
- F. URETERAL RESECTION MARGIN IS FREE OF MALIGNANCY.
- G. TNM STAGE: T3b; NX; M1.
- H. NON NEOPLASTIC KIDNEY WITH NO SIGNIFICANT PATHOLOGICAL CHANGE.

THE ADRENAL GLAND WITH NO SIGNIFICANT PATHOLOGICAL CHANGE.

COMMENT:

Most of the tumor cells show nuclear features consistent with a Fuhrman nuclear grade 3. However focal areas of the tumor show bizarre and polymorphic nuclei, consistent with a Fuhrman nuclear grade 4.

Source: NCI Genomic Data Commons file 967732ac-6fc2-40dc-8b62-2b010b133b77 (TCGA-B0-4819.A5A2E38D-F632-49FC-AE32-02A4FE05EEAB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).